Somatic mutation profile of tumor specimen TCGA-CD-8527-01A (aliquot TCGA-CD-8527-01A-11D-2340-08) from TCGA case TCGA-CD-8527, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 72.6 years (26,503 days).
Specimen TCGA-CD-8527-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27de7cd4-ab23-46b9-9ab7-18c680079434.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-8527-10A (Blood Derived Normal), aliquot TCGA-CD-8527-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d275a8c5-96c6-4922-9a74-7989d9e1748b

The open-access MAF lists 278 somatic variants for this specimen: 200 protein-altering or splice-affecting, 72 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 165, Silent 72, Splice Site 9, Frame Shift Del 9, Nonsense Mutation 8, In Frame Del 4, Frame Shift Ins 3, Intron 3, RNA 2, Splice Region 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.683A>G p.H228R | Missense Mutation (SNP) | VAF 43/151 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774589520, COSV57247786; called by muse, mutect2, varscan2
- PTPRD | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 26/60 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs764400127, COSV61926988, COSV61964410; called by muse, mutect2, varscan2
- ABCB4 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs140631210; called by muse, mutect2, varscan2
- ABCB5 | c.3528T>G p.I1176M (on ENST00000404938 / NM_001163941.2; = p.I731M on NM_178559.6) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV51714506; called by muse, mutect2, varscan2
- ACSL4 | c.1417G>A p.G473S (on ENST00000340800 / NM_022977.2; = p.G432S on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); catalogued as COSV61615123; called by muse, mutect2, varscan2
- AGAP6 | c.1633C>T p.R545C (on ENST00000374056 / NM_001365867.1; = p.R568C on NM_001077665.2) | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs782697526, COSV65017635; called by muse, mutect2, varscan2
- AHNAK2 | c.14807C>T p.P4936L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV60910634; called by muse, mutect2, varscan2
- AKAP13 | c.5108G>A p.R1703Q (on ENST00000394518 / NM_007200.5; = p.R1707Q on NM_006738.6) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs773469794, COSV63463959; called by muse, mutect2, varscan2
- AKAP3 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.087); catalogued as rs201140446, COSV57416155, COSV57422379; called by muse, mutect2, varscan2
- ALMS1 | c.3980C>T p.P1327L | Missense Mutation (SNP) | VAF 57/219 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs764135588, COSV52515153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD11 | c.2678G>A p.R893Q | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs1298734986, COSV56365526; called by muse, mutect2, varscan2
- ANKRD17 | c.4063A>G p.T1355A | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV58223444; called by muse, mutect2
- APOB | c.1952C>A p.A651D | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV51943206, COSV51953967; called by muse, mutect2, varscan2
- ARC | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 74/107 reads (69%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1460591873, COSV63078003; called by muse, mutect2, varscan2
- ARHGAP1 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs749420115, COSV56320669; called by muse, mutect2, varscan2
- ARHGAP36 | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs145932994, COSV52264862; called by muse, mutect2, varscan2
- ATP6V0A4 | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.389); catalogued as COSV59477794; called by muse, mutect2, varscan2
- AUTS2 | c.2692T>C p.S898P | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV61416356; called by muse, mutect2, varscan2
- AZGP1 | c.613+1G>A p.X205_splice | Splice Site (SNP) | VAF 426/961 reads (44%) | catalogued as rs112067579, COSV52798158; called by muse, mutect2, varscan2
- BMF | c.273A>T p.E91D | Missense Mutation (SNP) | VAF 100/129 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV55019365; called by muse, mutect2, varscan2
- BTN2A2 | c.1302G>T p.E434D | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as rs139419531, COSV61857899; called by muse, mutect2, varscan2
- CACNA1F | c.2375G>T p.G792V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as COSV59905584; called by muse, mutect2, varscan2
- CAMTA1 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV57913092; called by muse, mutect2, varscan2
- CC2D1B | c.942+2T>C p.X314_splice | Splice Site (SNP) | VAF 3/12 reads (25%) | catalogued as COSV52561367; called by muse, mutect2
- CCDC8 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.162); catalogued as rs867282286, COSV56774071; called by muse, mutect2, varscan2
- CCP110 | c.1529G>A p.S510N | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.07); catalogued as COSV66817370; called by muse, mutect2, varscan2
- CDH11 | c.490T>A p.Y164N | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51768834, COSV99219794; called by muse, mutect2
- CELSR2 | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as rs1488965696, COSV54775725; called by muse, mutect2, varscan2
- CENPF | c.7809C>A p.D2603E | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1027200080, COSV65276600; called by muse, mutect2, varscan2
- CFAP65 | c.1436T>G p.L479R | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55390935; called by muse, mutect2
- CHRM3 | c.1594C>A p.L532M | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55095077; called by muse, mutect2, varscan2
- CILP | c.2933G>A p.R978Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as rs373252930; called by muse, mutect2, varscan2
- CISH | c.518G>A p.S173N (on ENST00000348721 / NM_145071.4; = p.S190N on NM_013324.6) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs779764644, COSV62295151; called by muse, mutect2, varscan2
- CLK2 | c.938G>T p.R313L (on ENST00000368361 / NM_001294339.2; = p.R312L on NM_003993.4) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); catalogued as COSV100226789, COSV56946407; called by muse, mutect2, varscan2
- CMYA5 | c.1269G>T p.K423N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV71407485; called by muse, mutect2, varscan2
- COASY | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99888733; called by muse, mutect2, varscan2
- CORO7 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs745958172, COSV52032046; called by muse, mutect2, varscan2
- CPE | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780646997, COSV68581400; called by muse, mutect2, varscan2
- CSF2RA | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 129/181 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs148928173, COSV62625560; called by muse, mutect2, varscan2
- CSMD1 | c.6947G>A p.C2316Y (on ENST00000520002; = p.C2315Y on NM_033225.6) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59349053; called by muse, mutect2
- CSMD1 | c.4318T>G p.F1440V (on ENST00000520002; = p.F1439V on NM_033225.6) | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100142201, COSV59314221; called by muse, mutect2, varscan2
- CSNK1A1L | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 7/170 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV65789936; called by muse, mutect2
- CUX1 | c.2320G>A p.G774S | Missense Mutation (SNP) | VAF 62/250 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs141755950; called by muse, mutect2, varscan2
- CYP3A4 | c.165+2T>C p.X55_splice | Splice Site (SNP) | VAF 16/346 reads (5%) | catalogued as COSV60503125; called by muse, mutect2
- CYP7A1 | c.183G>T p.R61S | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV56964515; called by muse, mutect2, varscan2
- DACH2 | c.1661A>G p.D554G | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV64176970; called by muse, mutect2, varscan2
- DCC | c.3662A>G p.E1221G | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV71435355; called by muse, mutect2, varscan2
- DHRS7C | c.789G>A p.M263I (on ENST00000330255 / NM_001220493.2; = p.M262I on NM_001105571.3) | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV57651666; called by muse, mutect2, varscan2
- DLL1 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.885); catalogued as rs1050312172, COSV64538009; called by muse, mutect2, varscan2
- DMXL1 | c.8752C>T p.R2918* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as rs922036833, COSV60716306; called by muse, mutect2, varscan2
- DNAJB13 | c.620T>C p.I207T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.752); catalogued as COSV60270086; called by muse, mutect2, varscan2
- DNAJC11 | c.705-1G>A p.X235_splice | Splice Site (SNP) | VAF 56/123 reads (46%) | catalogued as rs1335267928, COSV53788509; called by muse, mutect2, varscan2
- DPPA4 | c.898A>C p.S300R | Missense Mutation (SNP) | VAF 48/236 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV59511559; called by muse, mutect2, varscan2
- EIF3F | c.112G>C p.V38L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV59142657; called by muse, mutect2, varscan2
- EIF4EBP2 | c.329T>C p.V110A | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV64667584; called by muse, mutect2, varscan2
- EML1 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 58/70 reads (83%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as rs749465112, COSV51747708; called by muse, mutect2, varscan2
- EPB41L2 | c.2453T>C p.V818A | Missense Mutation (SNP) | VAF 92/328 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV61357204; called by muse, mutect2, varscan2
- EPB41L4A | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs368470046; called by muse, mutect2, varscan2
- EPHA4 | c.2216A>T p.D739V | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56038231; called by muse, mutect2, varscan2
- ERAP2 | c.2604del p.Q869Sfs*3 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs753952011; called by mutect2, pindel, varscan2
- FAM47C | c.2266G>C p.E756Q | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.702); catalogued as COSV63728475; called by muse, mutect2, varscan2
- FASTKD1 | c.1210C>T p.L404F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV71624482; called by muse, mutect2, varscan2
- FAT4 | c.6839T>A p.L2280H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58696578, COSV58703108; called by muse, mutect2, varscan2
- FGF12 | c.569A>G p.K190R (on ENST00000454309 / NM_021032.5; = p.K128R on NM_004113.6) | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV53176360; called by muse, mutect2, varscan2
- FNDC7 | c.1528C>T p.R510W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.296); catalogued as rs375721141, COSV54755883; called by muse, mutect2, varscan2
- FOXG1 | c.832A>G p.T278A | Missense Mutation (SNP) | VAF 54/70 reads (77%) | SIFT tolerated (0.28); PolyPhen benign (0.168); catalogued as COSV57398049; called by muse, mutect2, varscan2
- GABRR3 | c.449A>G p.K150R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV72084200; called by muse, mutect2, varscan2
- GAL3ST3 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV61748635; called by muse, mutect2
- GAS8 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as rs750407315, COSV51944915; called by muse, mutect2, varscan2
- GCN1 | c.2273T>C p.V758A | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV56110941; called by muse, mutect2, varscan2
- GFI1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.137); catalogued as COSV54042524, COSV54043843; called by muse, mutect2, varscan2
- GJA4 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs750895718, COSV60725312, COSV60725705; called by muse, mutect2, varscan2
- GJC2 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64513098; called by muse, mutect2, varscan2
- GRM5 | c.2713G>C p.A905P | Missense Mutation (SNP) | VAF 78/299 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.987); catalogued as rs571599568, COSV59614926; called by muse, mutect2, varscan2
- GSE1 | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769714454, COSV53673768; called by muse, mutect2, varscan2
- GTF2H4 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.156); catalogued as COSV52559980; called by muse, mutect2, varscan2
- GUCY2F | c.2914A>T p.M972L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV54305380; called by muse, mutect2, varscan2
- HAND2 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64018496; called by muse, mutect2, varscan2
- IFT80 | c.2031A>G p.I677M | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV58449837; called by muse, mutect2, varscan2
- IRX6 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.386); catalogued as rs769775558, COSV51861266; called by muse, mutect2, varscan2
- ISM1 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs989433597, COSV52602677; called by muse, mutect2, varscan2
- JCAD | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 17/199 reads (9%) | catalogued as rs762905747, COSV64760643; called by muse, mutect2
- KCNH3 | c.1985T>C p.V662A | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57791718; called by muse, mutect2
- KIF3B | c.2180C>T p.S727F | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as rs141907829; called by muse, mutect2, varscan2
- KRT17 | c.1204+1G>A p.X402_splice | Splice Site (SNP) | VAF 17/68 reads (25%) | catalogued as rs753628412, COSV60860249; called by muse, mutect2, varscan2
- L1TD1 | c.337dup p.T113Nfs*13 | Frame Shift Ins (INS) | VAF 8/72 reads (11%) | catalogued as rs753466100; called by mutect2, pindel, varscan2
- LAMC2 | c.610G>T p.V204F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV51457589; called by muse, mutect2, varscan2
- LRAT | c.285G>C p.K95N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as COSV60477616; called by muse, mutect2, varscan2
- LRP1B | c.13143C>A p.N4381K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.979); catalogued as COSV67247677; called by muse, mutect2
- LRP1B | c.7020A>C p.Q2340H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV67247682; called by muse, mutect2, varscan2
- LRRK2 | c.7475G>T p.C2492F | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV54160983; called by muse, mutect2, varscan2
- MAGEB3 | c.104A>T p.K35M | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV100854749, COSV64397424, COSV64397481; called by muse, mutect2, varscan2
- MEGF11 | c.3007G>A p.G1003S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs754335032, COSV56544449; called by muse, mutect2, varscan2
- METAP1D | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs767523663, COSV59929659; called by muse, mutect2, varscan2
- MFSD5 | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV61565827; called by muse, mutect2
- MKNK2 | c.125G>A p.C42Y | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as COSV51733705; called by muse, mutect2, varscan2
- MLC1 | c.866T>A p.M289K | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV61117855; called by muse, varscan2
- MMP9 | c.1049C>A p.P350H | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63434254; called by muse, mutect2, varscan2
- MSLNL | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs376078479; called by muse, mutect2, varscan2
- MYCT1 | c.163A>C p.S55R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.366); catalogued as COSV65890731, COSV65891152; called by muse, mutect2, varscan2
- MYLK | c.4280A>C p.K1427T | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV60615109; called by muse, mutect2, varscan2
- NALCN | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.067); catalogued as rs894781933, COSV51949029; called by muse, mutect2, varscan2
- NBPF3 | c.1209-1G>C p.X403_splice | Splice Site (SNP) | VAF 11/31 reads (35%) | catalogued as COSV59061695; called by muse, mutect2, varscan2
- NCAM2 | c.1322T>A p.L441* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV53087946; called by muse, mutect2
- NID1 | c.2695G>A p.V899M | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs748671846, COSV51617969; called by muse, mutect2, varscan2
- NR1D1 | c.805T>G p.F269V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.096); catalogued as COSV52844674; called by muse, mutect2, varscan2
- NRXN3 | c.2174C>T p.T725M (on ENST00000335750 / NM_001330195.2; = p.T352M on NM_004796.6) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1404679790, COSV59735686, COSV59774691; called by muse, mutect2, varscan2
- NT5C1B | c.1388G>A p.R463H (on ENST00000359846 / NM_001199086.2; = p.R403H on NM_033253.4) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201567504, COSV58397396; called by muse, mutect2, varscan2
- NTSR2 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 68/130 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.207); catalogued as rs374573826; called by muse, mutect2, varscan2
- NYAP1 | c.951G>C p.K317N | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.822); catalogued as COSV55720294; called by muse, mutect2, varscan2
- OGA | c.821C>G p.A274G | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.232); catalogued as COSV63382342; called by muse, mutect2, varscan2
- OPHN1 | c.1352T>A p.F451Y | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (1); PolyPhen probably damaging (0.926); catalogued as COSV62784238; called by muse, mutect2, varscan2
- OR10X1 | c.193A>C p.T65P | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63767431; called by muse, mutect2, varscan2
- OR2F1 | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as rs1474111018, COSV67331682; called by muse, mutect2, varscan2
- OR2T3 | c.938G>C p.R313T | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.055); catalogued as COSV100613318, COSV62082892; called by muse, mutect2, varscan2
- OR5M10 | c.884G>C p.R295T | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as rs2852414; called by muse, mutect2, varscan2
- PCDH17 | c.2477C>A p.P826H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64976348; called by muse, mutect2, varscan2
- PCDHA3 | c.2377G>A p.V793I | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs1306203317, COSV63543040; called by muse, mutect2, varscan2
- PCDHB11 | c.2368C>T p.R790* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as rs1554285839, COSV61311264; called by muse, mutect2, varscan2
- PCDHGA12 | c.1723G>A p.V575M | Missense Mutation (SNP) | VAF 23/378 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.298); catalogued as rs768206517, COSV52758300; called by muse, mutect2
- PHLDB2 | c.505G>C p.G169R | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV67313593; called by muse, mutect2, varscan2
- PPP2R2D | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs781827357, COSV70778901; called by muse, mutect2, varscan2
- PRDM16 | c.1737C>G p.F579L | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV54598496; called by muse, mutect2, varscan2
- PRF1 | c.219C>A p.C73* | Nonsense Mutation (SNP) | VAF 25/46 reads (54%) | catalogued as rs1196309418, COSV64615436; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.440C>G p.T147S (on ENST00000421990 / NM_001136042.2; = p.T129S on NM_025267.3) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.214); catalogued as COSV64183708; called by muse, mutect2, varscan2
- QSOX1 | c.1399G>T p.V467L | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV62581026; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1265+1G>T p.X422_splice | Splice Site (SNP) | VAF 16/49 reads (33%) | catalogued as COSV51935512; called by muse, mutect2, varscan2
- RARRES2 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs772969637, COSV56231695; called by muse, mutect2, varscan2
- RBM25 | c.1218_1223del p.R425_E426del | In Frame Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs760856374; called by pindel, varscan2
- RIMS3 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV65503872, COSV65504931; called by muse, mutect2, varscan2
- RPRD2 | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.816); catalogued as rs776288719, COSV100955147, COSV64819183; called by muse, mutect2, varscan2
- RXYLT1 | c.1115C>A p.P372H | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54169150; called by muse, mutect2, varscan2
- RYR1 | c.9760G>A p.G3254R | Missense Mutation (SNP) | VAF 50/68 reads (74%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV62103201; called by muse, mutect2, varscan2
- SCGN | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs151030217; called by muse, mutect2, varscan2
- SCN1A | c.5620C>T p.R1874W (on ENST00000303395 / NM_001202435.3; = p.R1863W on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796053043, COSV57670031; ClinVar: uncertain significance; called by mutect2, varscan2
- SCN9A | c.3869G>A p.R1290Q (on ENST00000303354; = p.R1279Q on NM_002977.3) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs368396027, COSV57599715; called by muse, mutect2, varscan2
- SCNN1G | c.618+2T>A p.X206_splice | Splice Site (SNP) | VAF 12/179 reads (7%) | catalogued as COSV55600163; called by muse, mutect2
- SEC31A | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs747030120, COSV52348040; called by muse, mutect2, varscan2
- SEMA6A | c.2095A>G p.M699V | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV56712912; called by muse, mutect2, varscan2
- SIGLEC1 | c.4684G>A p.A1562T | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs773583320, COSV52467707; called by muse, mutect2, varscan2
- SIGLEC9 | c.1040A>G p.Q347R | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV99143146; called by muse, mutect2
- SLC12A2 | c.3628T>G p.F1210V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52473620; called by muse, mutect2, varscan2
- SLC26A4 | c.2120G>A p.G707E | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV55918134; called by muse, mutect2, varscan2
- SLC32A1 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV54147493; called by muse, mutect2, varscan2
- SLC4A5 | c.3236del p.K1079Rfs*29 | Frame Shift Del (DEL) | VAF 27/152 reads (18%) | catalogued as rs778293501; called by pindel, varscan2
- SLC6A2 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.481); catalogued as rs147833183; called by muse, mutect2, varscan2
- SLF2 | c.3182T>C p.V1061A | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.051); catalogued as COSV53276372; called by muse, mutect2, varscan2
- SNRNP200 | c.3268C>T p.R1090W | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1223054032, COSV60492019; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SOGA1 | c.722A>G p.E241G | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52924142; called by muse, mutect2, varscan2
- SP110 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.052); catalogued as rs114017623, COSV51253143; called by muse, mutect2, varscan2
- SPHKAP | c.4454G>C p.S1485T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV60886252; called by muse, mutect2, varscan2
- SPTA1 | c.1925A>C p.K642T | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as COSV63756474; called by muse, mutect2, varscan2
- SPTLC1 | c.1107G>C p.K369N | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated (0.73); PolyPhen benign (0.027); catalogued as COSV52765234; called by muse, mutect2, varscan2
- SSH1 | c.2706C>A p.F902L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58458076; called by muse, mutect2, varscan2
- SSX5 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 64/294 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0.021); catalogued as rs782229511, COSV100308753, COSV61255813; called by muse, mutect2, varscan2
- SYNE1 | c.11775A>C p.E3925D | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as COSV55034244; called by muse, mutect2, varscan2
- TBC1D16 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.021); catalogued as COSV60479370; called by muse, mutect2, varscan2
- TBC1D9B | c.2702T>A p.F901Y | Missense Mutation (SNP) | VAF 85/176 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62282910; called by muse, mutect2, varscan2
- TBX18 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.304); catalogued as rs376283250; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 18/91 reads (20%) | catalogued as rs758822980; called by mutect2, varscan2
- TMEM168 | c.70_73del p.N24Efs*3 | Frame Shift Del (DEL) | VAF 4/13 reads (31%) | catalogued as rs777558642; called by mutect2, varscan2
- TMPRSS6 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs200558933; called by muse, mutect2, varscan2
- TMTC2 | c.1601G>C p.G534A | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1292809568, COSV58275593; called by muse, varscan2
- TRAFD1 | c.1270A>T p.R424* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV57505160; called by muse, mutect2, varscan2
- TTC13 | c.2245T>A p.C749S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as COSV64169113; called by muse, mutect2, varscan2
- TTI2 | c.494C>A p.T165N | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV62453065; called by muse, mutect2
- TTN | c.75521A>G p.Y25174C (on ENST00000591111; = p.Y17750C on NM_003319.4) | Missense Mutation (SNP) | VAF 13/191 reads (7%) | PolyPhen probably damaging (1); catalogued as COSV60185030; called by muse, mutect2
- UGGT1 | c.3464A>C p.Q1155P | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52138474; called by muse, mutect2, varscan2
- UNC79 | c.6965G>T p.R2322M (on ENST00000393151 / NM_001346218.2; = p.R2145M on NM_020818.5) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV56397827; called by muse, mutect2, varscan2
- USP13 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 51/75 reads (68%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as rs144016604, COSV55867810; called by muse, mutect2, varscan2
- VARS2 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 14/77 reads (18%) | catalogued as rs753139152, COSV52559988; called by muse, mutect2, varscan2
- VDAC1 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.264); catalogued as COSV54737878; called by muse, mutect2, varscan2
- VPS33B | c.1590G>T p.E530D | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV60980869; called by muse, mutect2, varscan2
- WNK4 | c.1858C>A p.P620T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs781005656, COSV55907356; called by muse, mutect2, varscan2
- WNK4 | c.2411C>T p.S804L | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV55907378; called by muse, mutect2, varscan2
- ZC3H12B | c.2290G>A p.V764M | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs201974933, COSV59048132; called by muse, mutect2, varscan2
- ZCCHC24 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1451320763, COSV64886750; called by muse, mutect2, varscan2
- ZFYVE27 | c.807C>T p.D269= | Splice Region (SNP) | VAF 18/119 reads (15%) | catalogued as rs1458451162, COSV61746996; called by muse, mutect2, varscan2
- ZNF318 | c.2488C>T p.R830C | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.804); catalogued as rs763624474, COSV58934648; called by muse, mutect2, varscan2
- ZNF385B | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as rs745453004, COSV69800100, COSV69800409; called by muse, mutect2, varscan2
- ZNF398 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as rs769383002, COSV60065939; called by muse, mutect2, varscan2
- ZNF443 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.18); catalogued as COSV100042309; called by muse, mutect2, varscan2
- ZNF560 | c.1234G>C p.A412P | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV56869553; called by muse, mutect2, varscan2
- ZNF598 | c.766T>G p.F256V | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV70911125; called by muse, mutect2, varscan2
- ZNF615 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs147205148, COSV100943875, COSV65033109; called by muse, mutect2, varscan2
- ZNF705A | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV63733448; called by muse, mutect2, varscan2
- ZNF75D | c.603A>T p.R201S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV66133096; called by muse, mutect2, varscan2
- ACAP2 | c.723del p.K241Nfs*17 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | called by mutect2, pindel, varscan2
- ALOX12 | c.1161+3dup | Splice Region (INS) | VAF 21/63 reads (33%) | called by mutect2, pindel, varscan2
- CD96 | c.306_314del p.L103_L105del | In Frame Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- DOK7 | c.615del p.T206Pfs*40 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- KIAA1217 | c.4715dup p.F1573Vfs*2 | Frame Shift Ins (INS) | VAF 30/121 reads (25%) | called by mutect2, pindel, varscan2
- LIMK2 | c.310_334del p.I104Hfs*71 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel
- NLRC3 | c.2621_2623del p.L874del | In Frame Del (DEL) | VAF 6/19 reads (32%) | called by pindel, varscan2
- NRXN3 | c.2777+1dup | Frame Shift Ins (INS) | VAF 29/106 reads (27%) | called by mutect2, pindel, varscan2
- PSMD13 | c.83_95+13del p.X28_splice | Splice Site (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- SPATS2L | c.1016G>T p.C339F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.903); called by muse, mutect2
- TRIP12 | c.4770del p.K1590Nfs*4 | Frame Shift Del (DEL) | VAF 20/69 reads (29%) | called by mutect2, pindel, varscan2
- ZDHHC11 | c.131_151del p.V44_V50del | In Frame Del (DEL) | VAF 18/71 reads (25%) | called by pindel, varscan2
- ZDHHC11 | c.38del p.P13Qfs*19 | Frame Shift Del (DEL) | VAF 38/130 reads (29%) | called by pindel, varscan2
- AANAT | c.126G>T p.P42= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV51685489, COSV51685720; called by muse, mutect2, varscan2
- AGPS | c.1713C>T p.Y571= | Silent (SNP) | VAF 36/70 reads (51%) | catalogued as rs773126499, COSV51566477; ClinVar: likely benign; called by muse, mutect2, varscan2
- AL592490.1 | c.177C>T p.L59= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV69426963; called by muse, mutect2, varscan2
- APBB1 | c.156C>T p.S52= | Silent (SNP) | VAF 70/155 reads (45%) | catalogued as rs773191931, COSV54978210; called by muse, mutect2, varscan2
- APEX1 | c.9G>A p.K3= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV51658305; called by muse, mutect2, varscan2
- ATP2B4 | c.1935C>T p.F645= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as rs181836521, COSV58174547, COSV58176851; called by muse, mutect2, varscan2
- AURKC | c.231G>A p.S77= (on ENST00000302804 / NM_001015878.2; = p.S43= on NM_003160.3) | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs1568483946, COSV57139242; called by muse, mutect2, varscan2
- AUTS2 | c.1656C>A p.P552= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV61416348; called by muse, mutect2, varscan2
- BICC1 | c.456C>T p.G152= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV65862374; called by muse, mutect2, varscan2
- CCNF | c.1002C>T p.T334= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as rs545944447, COSV53541246; called by muse, mutect2, varscan2
- COASY | c.330G>T p.P110= | Silent (SNP) | VAF 58/272 reads (21%) | catalogued as COSV99888735; called by muse, mutect2, varscan2
- CYP11B2 | c.30C>T p.C10= | Silent (SNP) | VAF 102/308 reads (33%) | catalogued as rs752745892, COSV59996834; called by muse, mutect2, varscan2
- DBX1 | c.942G>A p.A314= | Silent (SNP) | VAF 53/131 reads (40%) | catalogued as COSV57053438; called by muse, mutect2, varscan2
- DDR2 | c.1530C>T p.V510= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs751266189, COSV63372476; called by muse, mutect2, varscan2
- DLL3 | c.1614C>T p.H538= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV52695563; called by muse, mutect2, varscan2
- ELFN2 | c.1896G>A p.S632= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs766332484, COSV68745344; called by muse, mutect2, varscan2
- GABBR1 | c.858G>A p.T286= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs374257753; called by muse, mutect2, varscan2
- GLUD2 | c.222C>T p.F74= | Silent (SNP) | VAF 54/96 reads (56%) | catalogued as rs1294342192, COSV60152465; called by muse, mutect2, varscan2
- GREB1 | c.4566T>C p.P1522= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV52191440; called by muse, mutect2
- GRM4 | c.168G>A p.P56= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs140904979; called by muse, mutect2, varscan2
- HMGCS1 | c.213T>C p.T71= | Silent (SNP) | VAF 35/143 reads (24%) | catalogued as rs759244537, COSV57290779; called by muse, mutect2, varscan2
- HS3ST6 | c.921G>A p.R307= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs1380325843, COSV53535777; called by muse, mutect2, varscan2
- IGLV5-48 | c.63T>C p.A21= | Silent (SNP) | VAF 42/156 reads (27%) | called by muse, mutect2, varscan2
- IRX2 | c.867C>T p.T289= | Silent (SNP) | VAF 16/21 reads (76%) | catalogued as rs1352397026, COSV57412304; called by muse, mutect2, varscan2
- KRT35 | c.1164C>G p.A388= | Silent (SNP) | VAF 38/140 reads (27%) | catalogued as COSV55843817; called by muse, mutect2, varscan2
- KRT36 | c.951C>T p.N317= | Silent (SNP) | VAF 21/31 reads (68%) | catalogued as rs542239551, COSV60202673; called by muse, mutect2, varscan2
- KRT6B | c.708C>T p.D236= | Silent (SNP) | VAF 64/252 reads (25%) | catalogued as COSV52884903; called by muse, varscan2
- KRT86 | c.51C>A p.A17= | Silent (SNP) | VAF 10/151 reads (7%) | catalogued as COSV53293589, COSV99525072; called by muse, mutect2
- LAMA2 | c.1758G>A p.A586= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs1371610402, COSV70351702; called by muse, mutect2, varscan2
- LANCL2 | c.1134G>T p.L378= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as COSV54650755; called by muse, mutect2, varscan2
- LPCAT1 | c.1335C>T p.L445= | Silent (SNP) | VAF 56/84 reads (67%) | catalogued as COSV52039457, COSV52039935; called by muse, mutect2, varscan2
- LRRK1 | c.2784C>T p.S928= | Silent (SNP) | VAF 71/96 reads (74%) | catalogued as rs137936039, COSV52618965; called by muse, mutect2, varscan2
- LRRK2 | c.391T>C p.L131= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV54160967; called by muse, mutect2, varscan2
- MAGEC2 | c.267G>A p.Q89= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV56000428; called by muse, mutect2, varscan2
- MAP2K6 | c.651A>G p.K217= | Silent (SNP) | VAF 31/132 reads (23%) | catalogued as COSV63006855; called by muse, mutect2, varscan2
- MAPK13 | c.456G>A p.K152= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV52983955; called by muse, mutect2, varscan2
- MAPT | c.2385G>A p.T795= (on ENST00000262410 / NM_001377265.1; = p.T403= on NM_005910.5) | Silent (SNP) | VAF 37/182 reads (20%) | catalogued as rs116567476, COSV52243453; called by muse, mutect2, varscan2
- MIA2 | c.2208A>G p.P736= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV54496561, COSV54502344; called by muse, mutect2
- MIB2 | c.2577G>A p.A859= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs752804806, COSV61543012; called by muse, mutect2, varscan2
- NAPRT | c.459G>A p.A153= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs763763850, COSV52787102; called by muse, mutect2, varscan2
- NCKIPSD | c.957G>A p.L319= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as COSV53662363; called by muse, mutect2, varscan2
- NOS1 | c.1716G>A p.V572= | Silent (SNP) | VAF 36/70 reads (51%) | catalogued as rs749731239, COSV57616508; called by muse, mutect2, varscan2
- NOS1 | c.1653C>A p.I551= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV57611365, COSV57616518; called by muse, mutect2, varscan2
- NTSR1 | c.570C>T p.S190= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV65138523; called by muse, mutect2, varscan2
- NYNRIN | c.3561C>A p.A1187= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV66843598; called by muse, mutect2, varscan2
- OR10K2 | c.420G>T p.V140= | Silent (SNP) | VAF 26/116 reads (22%) | catalogued as COSV59221939; called by muse, mutect2, varscan2
- OR8K1 | c.87G>A p.L29= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV54403470; called by muse, mutect2, varscan2
- PARP6 | c.1407C>A p.T469= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV53004044; called by muse, mutect2, varscan2
- PCDHGA11 | c.1644G>A p.S548= | Silent (SNP) | VAF 98/383 reads (26%) | catalogued as rs769543752, COSV53947486, COSV53984994; called by muse, mutect2, varscan2
- PDE4DIP | c.2404A>C p.R802= | Silent (SNP) | VAF 32/140 reads (23%) | catalogued as COSV57709535; called by muse, mutect2, varscan2
- PDS5A | c.1110T>C p.H370= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV57828172; called by muse, mutect2
- PHIP | c.1824C>T p.G608= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV51507136; called by muse, varscan2
- PLCB1 | c.990G>A p.S330= | Silent (SNP) | VAF 37/175 reads (21%) | catalogued as rs375950955; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPP1R3D | c.540G>A p.E180= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV62564697; called by muse, mutect2, varscan2
- PRICKLE2 | c.801G>A p.E267= (on ENST00000295902; = p.E211= on NM_198859.4) | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV55768691; called by muse, mutect2, varscan2
- PSD | c.1131G>T p.G377= | Silent (SNP) | VAF 26/119 reads (22%) | catalogued as COSV50050045; called by muse, mutect2, varscan2
- RHNO1 | c.162T>G p.T54= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100817068; called by muse, mutect2, varscan2
- ROBO2 | c.747A>G p.Q249= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs1329850020, COSV59923573; called by muse, mutect2, varscan2
- SEC14L3 | c.1074C>T p.A358= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as rs752956074, COSV53180550; called by muse, mutect2, varscan2
- SIX3 | c.870G>A p.T290= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV53227842; called by muse, mutect2, varscan2
- SLC16A6 | c.915A>G p.T305= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- SLC17A6 | c.465C>T p.F155= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs771516965, COSV54138604; called by muse, mutect2
- SPPL2C | c.549C>T p.I183= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as rs1482122596, COSV61292009; called by muse, mutect2, varscan2
- SPTAN1 | c.12T>C p.S4= | Silent (SNP) | VAF 56/123 reads (46%) | catalogued as COSV63988395; called by muse, mutect2, varscan2
- THOP1 | c.933G>A p.A311= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs759198628, COSV57019608; called by muse, mutect2, varscan2
- TMEM116 | c.282C>A p.G94= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as COSV61392913; called by muse, mutect2, varscan2
- TP63 | c.861G>A p.L287= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as rs545050848, COSV53212882; called by muse, mutect2, varscan2
- TRIB2 | c.654C>T p.Y218= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as rs765210830, COSV50227674; called by muse, mutect2, varscan2
- TST | c.747C>T p.R249= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs775393252, COSV50765332; called by muse, mutect2, varscan2
- ZBED4 | c.2820C>T p.F940= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs756539529, COSV53466748; called by muse, mutect2, varscan2
- ZNF385C | c.1035G>A p.P345= | Silent (SNP) | VAF 52/94 reads (55%) | catalogued as rs781833367, COSV100288824; called by muse, mutect2, varscan2
- ZNFX1 | c.3456C>T p.S1152= | Silent (SNP) | VAF 23/173 reads (13%) | catalogued as COSV65599394; called by muse, mutect2, varscan2
- EYA4 | c.1757-119C>T | Intron (SNP) | VAF 22/105 reads (21%) | catalogued as rs753799294, COSV62045020; called by muse, mutect2, varscan2
- FSTL4 | c.161-26623C>A | Intron (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99533491; called by muse, mutect2, varscan2
- RNF217-AS1 | n.1415G>A | RNA (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- SH3KBP1 | c.521-3653C>A | Intron (SNP) | VAF 36/128 reads (28%) | catalogued as COSV101115080; called by muse, mutect2, varscan2
- SSPOP | n.4345C>T | RNA (SNP) | VAF 15/60 reads (25%) | catalogued as rs777425533, COSV50488370; called by muse, mutect2, varscan2
- ZNF195 | c.*1G>C | 3'UTR (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99138133; called by muse, mutect2, varscan2
